Somatic mutation profile of tumor specimen TCGA-62-A46R-01A (aliquot TCGA-62-A46R-01A-11D-A24D-08) from TCGA case TCGA-62-A46R, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.9 years (20,063 days).
Specimen TCGA-62-A46R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a1ea736-4510-43b7-9cc8-11d437c1a50f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46R-10A (Blood Derived Normal), aliquot TCGA-62-A46R-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29ecd20-c063-4a22-8ea0-dc1c42fe9232

The open-access MAF lists 182 somatic variants for this specimen: 150 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 29, Nonsense Mutation 13, Frame Shift Del 7, Frame Shift Ins 3, Splice Site 2, RNA 1, Splice Region 1, Nonstop Mutation 1, 3'UTR 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs397514582, CM120577, COSV100610420; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV99908202; called by muse, mutect2
- ABCA9 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.05); catalogued as COSV100383344; called by muse, mutect2
- ABCG1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs200360236, COSV59207757; called by muse, mutect2, varscan2
- ACAN | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1162747201, COSV61357880; called by muse, mutect2, varscan2
- ACE2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99383011; called by muse, mutect2, varscan2
- ADAMTS5 | c.2049+2T>A p.X683_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99538079; called by muse, mutect2, varscan2
- APOB | c.5077C>A p.H1693N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.521); catalogued as COSV99266942; called by muse, mutect2, varscan2
- ARHGAP27 | c.1544T>A p.L515H (on ENST00000428638 / NM_001282290.1; = p.L174H on NM_199282.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100976579; called by mutect2, varscan2
- ARHGAP6 | c.2662G>A p.G888R (on ENST00000337414 / NM_013427.3; = p.G685R on NM_013423.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.601); catalogued as COSV100273357; called by muse, mutect2, varscan2
- ARHGEF17 | c.4076A>G p.D1359G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99736331; called by muse, mutect2, varscan2
- ARL4A | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.428); catalogued as COSV100775945; called by muse, mutect2, varscan2
- ATG2B | c.4966A>G p.T1656A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs373399335; called by muse, mutect2, varscan2
- ATXN7 | c.2471A>T p.H824L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99895012; called by muse, mutect2
- BPGM | c.119A>T p.N40I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV100790222; called by muse, mutect2, varscan2
- C21orf91 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99516134; called by muse, mutect2, varscan2
- C9orf135 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV101019903; called by muse, mutect2, varscan2
- CACNA1F | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1557110157, COSV100545171; called by muse, mutect2, varscan2
- CAPN6 | c.578T>A p.L193* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100136989; called by muse, mutect2, varscan2
- CCDC27 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.162); catalogued as COSV99622797; called by muse, mutect2, varscan2
- CHRNG | c.1136C>A p.S379* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV101264000; called by muse, mutect2, varscan2
- CLEC14A | c.570G>C p.L190F | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100643488; called by muse, mutect2
- CRNN | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as rs932714504, COSV99664266; called by muse, mutect2, varscan2
- CSMD1 | c.9485C>A p.P3162H (on ENST00000520002; = p.P3161H on NM_033225.6) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100151714, COSV100153736; called by muse, mutect2, varscan2
- CSMD1 | c.4401C>A p.N1467K (on ENST00000520002; = p.N1466K on NM_033225.6) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59288288; called by muse, mutect2, varscan2
- CT55 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99358935; called by muse, mutect2, varscan2
- DCAF8L1 | c.1291T>A p.Y431N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101491510; called by muse, mutect2, varscan2
- DMKN | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100303171; called by muse, mutect2
- DOK6 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.871); catalogued as rs558527260, COSV101234822, COSV66937122; called by muse, mutect2, varscan2
- EIF5A2 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99858756; called by muse, mutect2
- EPHA3 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs749114470, COSV100347240; called by muse, mutect2, varscan2
- EYS | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV100676909, COSV61000538; called by muse, mutect2, varscan2
- FAM161B | c.365C>A p.S122Y (on ENST00000651776; = p.S59Y on NM_152445.3) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV53178020; called by muse, mutect2, varscan2
- FCRLB | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100396297; called by muse, mutect2, varscan2
- FGD5 | c.2517C>G p.D839E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99548746; called by muse, mutect2, varscan2
- FLG | c.6676G>A p.G2226S | Missense Mutation (SNP) | VAF 122/348 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.237); catalogued as COSV100911896; called by muse, mutect2, varscan2
- FLG | c.4915G>A p.D1639N | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV64248788; called by muse, mutect2
- FLG | c.3950C>A p.A1317D | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV100911897; called by muse, mutect2, varscan2
- FLNA | c.3152C>A p.P1051H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV100774978; called by muse, mutect2, varscan2
- GABRA3 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100943165; called by muse, mutect2, varscan2
- GALNT13 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101223876; called by muse, mutect2, varscan2
- GOLGB1 | c.7019G>T p.G2340V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as COSV61470876; called by muse, mutect2, varscan2
- GPATCH2 | c.470C>G p.T157S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.079); catalogued as COSV100861413; called by muse, mutect2, varscan2
- GPBP1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99302983; called by muse, mutect2, varscan2
- GRAMD1B | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100455037; called by muse, mutect2, varscan2
- GRM4 | c.2212C>A p.R738S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV100946639, COSV65218945; called by muse, varscan2
- GYPC | c.191-1G>T p.X64_splice | Splice Site (SNP) | VAF 26/105 reads (25%) | catalogued as COSV99391942; called by muse, mutect2, varscan2
- HCFC1 | c.5935A>G p.I1979V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as COSV100129582; called by muse, mutect2, varscan2
- HECW1 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101222989, COSV101224096; called by muse, mutect2, varscan2
- HMCN1 | c.14312G>T p.R4771L | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV99633123; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.928A>T p.S310C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100676524; called by muse, mutect2, varscan2
- HRNR | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 8/239 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100912898; called by muse, mutect2
- HYDIN | c.15222C>G p.I5074M | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV101125156, COSV66638563; called by muse, mutect2
- IGHV3-53 | c.344C>A p.A115E | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as rs200767885; called by muse, varscan2
- ILF2 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.686); catalogued as COSV100721983; called by muse, mutect2, varscan2
- INTS1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV101248207; called by muse, mutect2
- ITSN2 | c.2467A>G p.K823E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.292); catalogued as rs1558510339, COSV100743950; called by muse, mutect2, varscan2
- KCNV1 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV52087507; called by muse, mutect2, varscan2
- KIAA0100 | c.3397C>A p.R1133S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101197365; called by muse, mutect2, varscan2
- KMT2E | c.974A>G p.N325S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs148942943; called by muse, mutect2, varscan2
- LAMB3 | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.382); catalogued as COSV99151727; called by muse, mutect2, varscan2
- LAS1L | c.608G>T p.R203M | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100408644, COSV56706662; called by muse, mutect2, varscan2
- LCE1E | c.178T>A p.C60S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.765); catalogued as COSV100908570; called by muse, mutect2, varscan2
- LYZL2 | c.434C>T p.S145L (on ENST00000375318; = p.S99L on NM_183058.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV100940622; called by muse, mutect2
- MAGEB4 | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974905, COSV66776727; called by muse, mutect2, varscan2
- MAGEC1 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99596187; called by muse, mutect2, varscan2
- MCTS1 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100989175; called by muse, mutect2, varscan2
- MCUR1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101001901; called by muse, mutect2, varscan2
- MKI67 | c.8707A>T p.R2903* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as COSV100896852; called by muse, varscan2
- MUC6 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as COSV101424708; called by muse, mutect2, varscan2
- MXRA5 | c.4378C>A p.L1460I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99475380; called by muse, mutect2, varscan2
- MYH4 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs777588594, COSV55114024; called by mutect2, varscan2
- MYO3B | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100511151; called by muse, mutect2, varscan2
- NBAS | c.6821A>G p.Q2274R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as COSV99871037; called by muse, mutect2, varscan2
- NDUFA1 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs1202692911, COSV65098092; called by muse, mutect2
- NELL1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100123440, COSV54288122; called by muse, mutect2, varscan2
- NOTCH1 | c.5081A>G p.Q1694R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV99490244; called by mutect2, varscan2
- NPR3 | c.1248C>A p.F416L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99423628; called by muse, mutect2, varscan2
- OR10X1 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV63767721; called by muse, mutect2, varscan2
- OR13C2 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV101604885; called by muse, mutect2, varscan2
- OR51I1 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.356); catalogued as COSV100971726; called by muse, mutect2, varscan2
- PCDH17 | c.3039del p.N1014Tfs*6 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as COSV64978186; called by mutect2, pindel, varscan2
- PCDHAC1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53850380; called by muse, mutect2, varscan2
- PCDHB3 | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.652); catalogued as rs782635342, COSV99166011; called by muse, mutect2
- PEX26 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV100299137; called by muse, mutect2, varscan2
- PJVK | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.323); catalogued as rs199693434; called by muse, mutect2
- PKP2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV50736430, COSV99298189; called by muse, mutect2, varscan2
- PLEKHM3 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV101216770; called by muse, mutect2, varscan2
- PPP1R3A | c.2834C>A p.P945H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV99493688; called by muse, mutect2, varscan2
- PRKAA2 | c.1197A>T p.K399N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100982998; called by muse, mutect2, varscan2
- PRKAG2 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99835714; called by muse, mutect2, varscan2
- PTPRD | c.3994G>C p.A1332P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as COSV100645953, COSV61927267; called by muse, mutect2, varscan2
- PTPRT | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626005; called by muse, mutect2, varscan2
- PXDNL | c.4090G>A p.D1364N | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100685265; called by muse, mutect2, varscan2
- RAG1 | c.989C>A p.S330Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.553); catalogued as COSV100201055, COSV55026039; called by muse, mutect2, varscan2
- RALGAPA1 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99355573; called by muse, mutect2, varscan2
- RASGRP4 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs142842646; called by muse, mutect2, varscan2
- RTL6 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100373840; called by muse, mutect2
- RYR2 | c.1612G>C p.A538P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100772057; called by muse, mutect2, varscan2
- RYR2 | c.12739G>T p.A4247S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as COSV100772058; called by muse, mutect2
- RYR3 | c.9584C>T p.A3195V (on ENST00000389232; = p.A3196V on NM_001036.6) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751655949, COSV101213461; called by muse, mutect2, varscan2
- SCN7A | c.4288G>C p.V1430L | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV101313317; called by muse, mutect2, varscan2
- SELL | c.299A>G p.Y100C (on ENST00000650983; = p.Y87C on NM_000655.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357711; called by muse, mutect2, varscan2
- SERPINA10 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV100003955; called by muse, mutect2, varscan2
- SF3B1 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV100135337, COSV59210895; called by muse, mutect2
- SLC18A2 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100041895; called by muse, mutect2, varscan2
- SLC25A37 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99264085; called by muse, mutect2, varscan2
- SLC32A1 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54146001, COSV99462525; called by muse, mutect2, varscan2
- SLC4A3 | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs757002521, COSV56096143; called by muse, mutect2, varscan2
- SLCO1B3 | c.1655G>A p.G552D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV99681980; called by muse, mutect2, varscan2
- SNAI2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50078935; called by muse, mutect2, varscan2
- SNX11 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as rs780438947, COSV100821788; called by muse, mutect2, varscan2
- SNX14 | c.1838T>C p.V613A (on ENST00000314673 / NM_001350535.1; = p.V560A on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV100121704; called by muse, mutect2, varscan2
- SPARC | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs142207246; called by muse, mutect2, varscan2
- SPTY2D1 | c.618A>C p.E206D | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100311774; called by muse, mutect2, varscan2
- STAP1 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55328136; called by muse, mutect2, varscan2
- STKLD1 | c.177G>A p.V59= | Splice Region (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100912162; called by muse, mutect2, varscan2
- SYT1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99696690; called by muse, mutect2, varscan2
- TECTA | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99880894; called by muse, mutect2, varscan2
- TNN | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV99512582; called by muse, mutect2, varscan2
- TRPM2 | c.2877C>G p.N959K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100309124; called by muse, mutect2, varscan2
- TTN | c.66143C>T p.T22048I (on ENST00000591111; = p.T14624I on NM_003319.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | PolyPhen possibly damaging (0.859); catalogued as COSV100623004; called by muse, mutect2, varscan2
- URGCP | c.1516C>T p.Q506* (on ENST00000453200 / NM_001077663.3; = p.Q497* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV99787696; called by muse, mutect2, varscan2
- VNN3 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV99258272; called by muse, mutect2, varscan2
- VPS13C | c.11260T>G p.*3754Eext*19 (on ENST00000644861 / NM_020821.3; = p.*3711Eext*19 on NM_017684.5) | Nonstop Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as COSV99829539; called by muse, mutect2, varscan2
- WNK3 | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100671866; called by muse, mutect2
- YY2 | c.674C>A p.P225Q | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100810821; called by muse, mutect2, varscan2
- ZAN | c.7249G>A p.V2417I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs536210909, COSV61805538; called by muse, mutect2, varscan2
- ZMYM3 | c.1043C>A p.S348* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100078192; called by muse, mutect2
- ZNF280A | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV100131162; called by muse, mutect2, varscan2
- ZNF474 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs533290881, COSV99682242; called by muse, mutect2, varscan2
- ZNF521 | c.3176A>T p.Q1059L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100832963; called by muse, mutect2, varscan2
- ZNF616 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100348512, COSV100348680; called by muse, mutect2, varscan2
- ZNF76 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV57591414, COSV99987828; called by muse, mutect2, varscan2
- ZNF804B | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100303155; called by muse, mutect2
- ACADS | c.165del p.I56Lfs*16 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- BCHE | c.1317dup p.W440Mfs*4 | Frame Shift Ins (INS) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- DCAF7 | c.645_646del p.Y216Rfs*19 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- ENOX2 | c.1591_1594delinsCCT p.S531Pfs*7 (on ENST00000338144 / NM_001382520.1; = p.S502Pfs*7 on NM_006375.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by pindel, varscan2*
- FAM131B | c.717dup p.P240Tfs*19 | Frame Shift Ins (INS) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- FOXP3 | c.595del p.C199Afs*55 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- HERC2 | c.4106del p.G1369Afs*37 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- HSFX1 | c.36T>A p.C12* | Nonsense Mutation (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LIF | c.456del p.C153Afs*14 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- QKI | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- SMAD1 | c.471dup p.N158* | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- XAGE2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- AIM2 | c.354C>T p.V118= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs759309655, COSV100931121; called by muse, mutect2, varscan2
- ATP10B | c.3054G>A p.L1018= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100515475; called by muse, mutect2, varscan2
- BDP1 | c.7488A>G p.S2496= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100703066; called by muse, mutect2, varscan2
- CA14 | c.117G>A p.E39= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1214234239, COSV100810010; called by muse, mutect2, varscan2
- DOCK1 | c.2601C>T p.L867= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54763512; called by muse, mutect2, varscan2
- ECE1 | c.711C>T p.F237= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1162930156, COSV99942142; called by muse, mutect2, varscan2
- FAM47C | c.2184G>A p.P728= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs149639130, COSV63726592; called by muse, mutect2, varscan2
- FLNA | c.3153C>G p.P1051= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs782289085, COSV100774977; called by muse, mutect2, varscan2
- GUCY1A2 | c.879C>T p.I293= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99972946; called by muse, mutect2, varscan2
- IGHV1-69 | c.144C>T p.F48= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs540092853; called by mutect2, varscan2
- ITGA7 | c.1743G>A p.R581= (on ENST00000555728; = p.R537= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99150794; called by muse, mutect2, varscan2
- LRFN4 | c.444G>A p.E148= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100540860; called by muse, mutect2, varscan2
- MAPKAPK2 | c.957T>C p.F319= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as rs1553432731, COSV99686076; called by muse, mutect2, varscan2
- MTA1 | c.807C>A p.I269= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100495378; called by muse, mutect2
- NAA15 | c.573A>G p.E191= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99649812; called by muse, mutect2, varscan2
- OLFML2B | c.1764C>T p.Y588= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1481370323, COSV99668715; called by muse, mutect2, varscan2
- OR6X1 | c.345C>T p.I115= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100020559, COSV100020620; called by muse, mutect2, varscan2
- PASD1 | c.819G>A p.L273= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100949500; called by muse, mutect2, varscan2
- PLXNA1 | c.5307G>T p.T1769= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99303785; called by muse, mutect2, varscan2
- PRKX | c.421C>A p.R141= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99468413; called by muse, mutect2
- RSBN1 | c.2076G>T p.V692= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99793483; called by muse, mutect2, varscan2
- SDCCAG8 | c.1536G>A p.Q512= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100654473; called by muse, mutect2
- STK33 | c.348T>C p.Y116= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100174322; called by muse, mutect2, varscan2
- TCERG1 | c.1302A>G p.E434= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as COSV57038236; called by muse, mutect2, varscan2
- TEX13A | c.375G>A p.A125= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs913418680, COSV100781731; called by muse, mutect2, varscan2
- TOX2 | c.15C>A p.R5= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100364380; called by muse, mutect2, varscan2
- UGT1A1 | c.264G>T p.V88= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV100529367, COSV100530652; called by muse, mutect2, varscan2
- USH2A | c.7710A>G p.L2570= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV56388347; called by muse, mutect2, varscan2
- WDTC1 | c.1095G>A p.V365= (on ENST00000319394 / NM_001276252.2; = p.V364= on NM_015023.5) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100089292; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829182 G>A | 3'Flank (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- GTPBP3 | c.*2G>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100259014, COSV61413054; called by muse, mutect2, varscan2
- SSPOP | n.11726C>A | RNA (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100946880, COSV100947793; called by muse, mutect2, varscan2
